FM case AD5108 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/2dce2e74-8363-406e-9a52-d69bac23eb0f

Female, 54.1 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
